Somatic mutation profile of tumor specimen ALCH-B4KI-TTP1-A (aliquot ALCH-B4KI-TTP1-A-1-0-D-A81V-36) from ALCHEMIST case ALCH-B4KI, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 68.8 years (25,133 days).
Specimen ALCH-B4KI-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8ce8e5b1-da3e-445b-badb-b8b1472929ff.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B4KI-NB1-A (Blood Derived Normal), aliquot ALCH-B4KI-NB1-A-1-0-D-A81V-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0d79384c-d970-4105-8645-f230cfc1964c

The open-access MAF lists 46 somatic variants for this specimen: 34 protein-altering or splice-affecting, 8 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, Silent 8, Intron 2, Nonsense Mutation 2, 5'UTR 2, Frame Shift Del 1, Splice Region 1, Frame Shift Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NFE2L2 | c.70T>C p.W24R | Missense Mutation (SNP) | VAF 20/59 reads (34%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1328994103, COSV67960091, COSV67960815, COSV67963035; called by muse, mutect2
- ABLIM1 | c.1046C>T p.T349I | Missense Mutation (SNP) | VAF 47/149 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.168); catalogued as COSV53309103; called by muse, mutect2, varscan2
- IL1B | c.772G>A p.D258N | Missense Mutation (SNP) | VAF 6/134 reads (4%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.94); catalogued as rs1191503899; called by muse, mutect2
- NBEAL2 | c.3250G>A p.D1084N | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as rs1220116955; called by muse, mutect2
- PTGFRN | c.1745G>A p.R582H | Missense Mutation (SNP) | VAF 42/117 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as rs376621300; called by muse, mutect2, varscan2
- RPA4 | c.694G>A p.V232I | Missense Mutation (SNP) | VAF 35/110 reads (32%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV61285823; called by muse, mutect2, varscan2
- SETD2 | c.7645C>T p.Q2549* | Nonsense Mutation (SNP) | VAF 36/142 reads (25%) | catalogued as rs1210400257; called by muse, mutect2, varscan2
- SFMBT2 | c.2080C>T p.R694* | Nonsense Mutation (SNP) | VAF 34/121 reads (28%) | catalogued as rs1481807825; called by muse, mutect2, varscan2
- SYNE1 | c.3148C>T p.P1050S (on ENST00000367255 / NM_182961.4; = p.P1057S on NM_033071.3) | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54919197; called by muse, mutect2, varscan2
- TBX1 | c.364G>A p.E122K | Missense Mutation (SNP) | VAF 14/123 reads (11%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.677); catalogued as rs1228619238; called by muse, mutect2
- THSD4 | c.554C>T p.T185M | Missense Mutation (SNP) | VAF 32/111 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.037); catalogued as rs200233214; called by mutect2, varscan2
- TMEM256 | c.218C>T p.S73F | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.701); catalogued as COSV56658585; called by muse, mutect2, varscan2
- TYK2 | c.3308G>A p.S1103N | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.639); catalogued as rs757843261; called by muse, mutect2
- ANKRD36C | c.1279G>C p.E427Q | Missense Mutation (SNP) | VAF 25/119 reads (21%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- BRPF3 | c.659A>G p.D220G | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CDAN1 | c.3568G>A p.E1190K | Missense Mutation (SNP) | VAF 16/296 reads (5%) | SIFT tolerated (0.81); PolyPhen benign (0.001); called by muse, mutect2
- DENND5B | c.1719T>A p.N573K | Missense Mutation (SNP) | VAF 37/139 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.472); called by muse, mutect2, varscan2
- DNAH3 | c.9712A>C p.I3238L | Missense Mutation (SNP) | VAF 30/89 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- GFM2 | c.1902dup p.C635Mfs*48 | Frame Shift Ins (INS) | VAF 7/24 reads (29%) | called by mutect2, pindel, varscan2
- GPR37 | c.939C>G p.F313L | Missense Mutation (SNP) | VAF 12/189 reads (6%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.557); called by muse, mutect2
- GRM8 | c.1429C>A p.Q477K | Missense Mutation (SNP) | VAF 18/238 reads (8%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.824); called by muse, mutect2
- HPS3 | c.217+3G>T | Splice Region (SNP) | VAF 25/64 reads (39%) | called by muse, mutect2, varscan2
- IGLV4-3 | c.171G>T p.Q57H | Missense Mutation (SNP) | VAF 9/179 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- JAG2 | c.527A>T p.D176V | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.892); called by muse, mutect2
- MCM9 | c.958G>C p.V320L | Missense Mutation (SNP) | VAF 49/191 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- PHGDH | c.76G>A p.G26R | Missense Mutation (SNP) | VAF 11/143 reads (8%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.587); called by muse, mutect2
- PLEKHG6 | c.606+1G>C p.X202_splice | Splice Site (SNP) | VAF 22/65 reads (34%) | called by muse, mutect2, varscan2
- PPWD1 | c.1402G>A p.V468I | Missense Mutation (SNP) | VAF 5/99 reads (5%) | SIFT tolerated (0.4); PolyPhen benign (0.015); called by muse, mutect2
- PRR23D1 | c.185A>C p.Y62S | Missense Mutation (SNP) | VAF 28/130 reads (22%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2, varscan2
- RARA | c.673T>A p.W225R | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SETD2 | c.1695_1717del p.K565Nfs*8 | Frame Shift Del (DEL) | VAF 16/53 reads (30%) | called by mutect2, pindel, varscan2
- SLC6A19 | c.527G>T p.W176L | Missense Mutation (SNP) | VAF 14/194 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); called by muse, mutect2
- TAF6L | c.1508G>T p.R503L | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.007); called by muse, varscan2
- USH2A | c.4051G>A p.A1351T | Missense Mutation (SNP) | VAF 13/130 reads (10%) | SIFT tolerated (0.57); PolyPhen benign (0.007); called by muse, mutect2
- ADGRB1 | c.1497C>T p.Y499= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as rs550583120; called by mutect2, varscan2
- C1GALT1C1 | c.876G>T p.G292= | Silent (SNP) | VAF 19/68 reads (28%) | called by muse, varscan2
- CCR6 | c.567C>T p.Y189= | Silent (SNP) | VAF 18/78 reads (23%) | called by muse, mutect2, varscan2
- FBF1 | c.2032C>A p.R678= (on ENST00000586717; = p.R692= on NM_001319193.1) | Silent (SNP) | VAF 15/77 reads (19%) | called by muse, mutect2, varscan2
- FH | c.138C>T p.S46= | Silent (SNP) | VAF 8/171 reads (5%) | catalogued as COSV100844982; called by muse, mutect2
- MEI1 | c.771G>T p.V257= | Silent (SNP) | VAF 29/118 reads (25%) | called by muse, mutect2, varscan2
- RCBTB2 | c.336C>T p.V112= | Silent (SNP) | VAF 20/66 reads (30%) | called by muse, varscan2
- TGM2 | c.1050G>T p.G350= | Silent (SNP) | VAF 24/83 reads (29%) | catalogued as rs1485217659; called by muse, mutect2, varscan2
- ADI1 | c.420+40G>A | Intron (SNP) | VAF 5/13 reads (38%) | catalogued as rs1301724826; called by muse, mutect2, varscan2
- CDKN1B | c.-19G>C | 5'UTR (SNP) | VAF 49/234 reads (21%) | called by muse, mutect2, varscan2
- CHD2 | c.-2A>T | 5'UTR (SNP) | VAF 62/302 reads (21%) | called by muse, varscan2
- NUP62CL | c.530+2217A>C | Intron (SNP) | VAF 35/152 reads (23%) | called by muse, mutect2, varscan2
